Somatic mutation profile of tumor specimen TCGA-55-6712-01A (aliquot TCGA-55-6712-01A-11D-1855-08) from TCGA case TCGA-55-6712, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-55-6712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a7f21af-fa1d-4d2f-903c-f449b88cc442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6712-10A (Blood Derived Normal), aliquot TCGA-55-6712-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6008513a-7173-4acb-b77d-33218c1275ad

The open-access MAF lists 145 somatic variants for this specimen: 100 protein-altering or splice-affecting, 44 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 44, Nonsense Mutation 11, Splice Site 6, Frame Shift Del 6, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121909284, CM040665, CM960013, COSV66359807; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA6 | c.4531G>C p.E1511Q | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV52636870; called by muse, mutect2
- AC093525.2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | PolyPhen benign (0.003); catalogued as COSV53549638, COSV53550148; called by muse, mutect2
- ADAMTS9 | c.5749G>A p.G1917S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55777370; called by muse, mutect2, varscan2
- AGR2 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101290830; called by muse, mutect2, varscan2
- ALDH4A1 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV99312278; called by muse, mutect2, varscan2
- ATP13A5 | c.239A>T p.D80V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60867345; called by muse, mutect2, varscan2
- BAIAP2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100348731; called by muse, mutect2
- CAMSAP2 | c.1870C>G p.H624D (on ENST00000236925 / NM_001297707.2; = p.H613D on NM_203459.3) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV52668245; called by muse, mutect2, varscan2
- CASP8AP2 | c.5692C>G p.P1898A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV52745912, COSV99387042; called by muse, mutect2, varscan2
- CMYA5 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV71404654, COSV71406189; called by muse, mutect2, varscan2
- COL1A2 | c.891+1G>T p.X297_splice | Splice Site (SNP) | VAF 27/99 reads (27%) | catalogued as COSV51955169; called by muse, mutect2, varscan2
- COL9A1 | c.2125G>C p.G709R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57880892; called by muse, mutect2, varscan2
- COQ6 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV53180284; called by muse, mutect2
- CPNE6 | c.1094G>C p.R365P | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53743181, COSV53743646; called by muse, mutect2, varscan2
- CREB5 | c.1507G>T p.D503Y (on ENST00000357727 / NM_182898.4; = p.D496Y on NM_004904.3) | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV63218605; called by muse, mutect2
- CRISPLD1 | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV51545798; called by muse, mutect2, varscan2
- CYP4F2 | c.973T>C p.F325L | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1163693497, COSV50000604; called by muse, mutect2, varscan2
- CYP4V2 | c.987+1G>T p.X329_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | catalogued as COSV66505348; called by muse, mutect2, varscan2
- DEPDC1B | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54008772; called by muse, mutect2
- DNAH2 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV50013586; called by muse, mutect2
- DOK6 | c.410-1G>C p.X137_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV66927991, COSV66939002; called by muse, mutect2, varscan2
- DOP1B | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs752679000, COSV67692596; called by mutect2, varscan2
- ELOVL4 | c.168T>G p.Y56* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV63953538; called by muse, mutect2
- EYS | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as COSV60980383; called by muse, mutect2, varscan2
- FAM126B | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99628201; called by muse, mutect2
- GRIA4 | c.1477-1G>C p.X493_splice | Splice Site (SNP) | VAF 12/120 reads (10%) | catalogued as COSV56887332; called by muse, mutect2, varscan2
- GRIK4 | c.2184G>T p.E728D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV70800951; called by muse, mutect2, varscan2
- HEATR5B | c.5693C>G p.P1898R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as COSV51850621; called by muse, mutect2, varscan2
- HELZ | c.2577G>C p.R859S | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV62377097; called by muse, mutect2
- IGSF1 | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100812286; called by muse, mutect2, varscan2
- IL5RA | c.520A>G p.R174G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56521979; called by muse, mutect2, varscan2
- ITGAD | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs749387931, COSV66757223; called by muse, mutect2
- KCNJ3 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54533558, COSV99715872; called by muse, varscan2
- KLHL13 | c.99-1G>C p.X33_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53245906; called by muse, mutect2, varscan2
- KLHL4 | c.2110A>G p.N704D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.468); catalogued as COSV64140221; called by muse, mutect2
- KRT79 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57939044; called by muse, mutect2, varscan2
- KRTAP10-10 | c.607T>A p.C203S | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV59955954; called by muse, mutect2, varscan2
- KRTAP20-2 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 14/205 reads (7%) | PolyPhen benign (0.076); catalogued as COSV100424542, COSV58183954; called by muse, mutect2
- LIN7C | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV53414601, COSV53414782; called by muse, mutect2, varscan2
- MAGEE1 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.354); catalogued as COSV63909303; called by muse, mutect2
- MET | c.3941A>G p.E1314G | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV59258840; called by muse, mutect2, varscan2
- MFSD12 | c.1224G>C p.M408I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV61535026; called by muse, mutect2, varscan2
- MPP3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV68197802; called by muse, mutect2, varscan2
- MUC16 | c.33631C>G p.L11211V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.053); catalogued as rs997337521, COSV67453872, COSV67460909; called by muse, mutect2, varscan2
- MUC16 | c.16417C>T p.Q5473* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV67453878, COSV67462441; called by muse, mutect2, varscan2
- MUC16 | c.16076C>T p.P5359L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.475); catalogued as COSV67453885; called by muse, varscan2
- NAA25 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.085); catalogued as COSV55703062; called by muse, mutect2, varscan2
- NACC1 | c.1521G>T p.E507D | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV99457252; called by muse, mutect2, varscan2
- NACC1 | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV99457258; called by muse, mutect2, varscan2
- NKAIN2 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63700980; called by muse, mutect2, varscan2
- NOP56 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61389344; called by muse, mutect2, varscan2
- ODAM | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV68572452; called by muse, mutect2, varscan2
- OR2H2 | c.615G>C p.L205F | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV100590016; called by muse, mutect2, varscan2
- OR2L3 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63454788; called by muse, mutect2, varscan2
- PATJ | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV57158024; called by muse, mutect2, varscan2
- PAXIP1 | c.2968A>G p.T990A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); catalogued as COSV66898082; called by muse, mutect2, varscan2
- PCDHB4 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV52020769; called by muse, mutect2, varscan2
- PCDHGA4 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.037); catalogued as rs764785344, COSV53909981; called by muse, mutect2, varscan2
- PDGFRA | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1553905281, COSV57266216; ClinVar: uncertain significance; called by muse, mutect2
- PILRB | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 12/160 reads (8%) | catalogued as COSV60333600; called by muse, mutect2
- POLE | c.6144C>G p.I2048M | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV57676819; called by muse, mutect2, varscan2
- PON3 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs200038070, COSV55698550, COSV55699275; called by muse, mutect2
- PRRX1 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV53412108; called by muse, mutect2, varscan2
- RGS8 | c.469G>C p.D157H (on ENST00000367556 / NM_001369564.2; = p.D175H on NM_033345.3) | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51115438; called by muse, mutect2, varscan2
- RP1L1 | c.6685G>A p.E2229K | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.431); catalogued as COSV66753148; called by muse, mutect2
- SALL1 | c.1620C>A p.S540R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV51755035; called by muse, mutect2, varscan2
- SDHD | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.171); catalogued as COSV54777693; called by muse, mutect2
- SH3KBP1 | c.1745G>C p.G582A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs755280140, COSV65646471; called by muse, mutect2, varscan2
- SLC6A6 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs761829964, COSV62648350; called by muse, mutect2, varscan2
- SMG7 | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV61630317; called by muse, mutect2, varscan2
- SMYD5 | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV50264504; called by muse, mutect2
- TARBP1 | c.4492C>T p.Q1498* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV50180686; called by muse, mutect2
- TBC1D3I | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs201473096; called by muse, mutect2, varscan2
- TEX15 | c.1939G>A p.E647K (on ENST00000256246; = p.E1030K on NM_001350162.2) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.319); catalogued as rs1462041378, COSV56343563; called by muse, mutect2, varscan2
- TEX35 | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.058); catalogued as COSV51103928; called by muse, mutect2
- THADA | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1174263513, COSV57676761; called by muse, mutect2
- TNR | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV54876364; called by muse, mutect2, varscan2
- TP53 | c.1015del p.E339Rfs*6 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; called by mutect2, pindel, varscan2
- TTYH3 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1406471521, COSV51859261; called by muse, mutect2
- UBR5 | c.6470G>A p.G2157E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV55282854; called by muse, mutect2
- USH2A | c.7733C>T p.T2578I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV56343018; called by muse, mutect2, varscan2
- USH2A | c.4520C>A p.S1507* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV56343034; called by muse, mutect2, varscan2
- UTRN | c.9738G>C p.Q3246H | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV62308306; called by muse, mutect2
- ZAN | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61806772; called by muse, mutect2, varscan2
- ZFP36L1 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 14/204 reads (7%) | catalogued as COSV60544191, COSV60544799; called by muse, mutect2
- ZNF195 | c.1637G>C p.G546A (on ENST00000399602 / NM_001130520.3; = p.G474A on NM_007152.5) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV99138238; called by muse, mutect2, varscan2
- ZNF479 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 11/148 reads (7%) | catalogued as COSV58637072; called by muse, mutect2
- ZNF566 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.138); catalogued as COSV67573410; called by muse, mutect2
- ZNF623 | c.1460A>G p.Y487C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1449229882, COSV71697073; called by muse, mutect2, varscan2
- ARID2 | c.2480_2496del p.Q827Lfs*8 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- DAPK1 | c.2751-1_2757del p.X917_splice | Splice Site (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- GPRC5A | c.561G>C p.L187F | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGA | c.6818_6824del p.H2273Rfs*60 (on ENST00000219905 / NM_001164273.1; = p.H2064Rfs*60 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- NCOR2 | c.573dup p.K192* | Frame Shift Ins (INS) | VAF 20/186 reads (11%) | called by mutect2, pindel, varscan2
- NPAP1 | c.538del p.S181Afs*41 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- PCLO | c.12941del p.L4314Qfs*3 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel*
- PRAMEF19 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- TMEM270 | c.788_789del p.P263Qfs*? | Frame Shift Del (DEL) | VAF 22/148 reads (15%) | called by mutect2, pindel, varscan2
- UBR5 | c.6469G>A p.G2157R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2
- ABI2 | c.1071C>G p.A357= (on ENST00000295851 / NM_001375719.1; = p.A290= on NM_005759.7 and 35 other RefSeq transcripts) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV53690635; called by muse, mutect2, varscan2
- ARMT1 | c.948G>A p.G316= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs762855990, COSV66178438; called by muse, mutect2, varscan2
- C6 | c.1464C>A p.A488= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV54707287; called by muse, varscan2
- CACNA1C | c.717C>T p.F239= | Silent (SNP) | VAF 24/356 reads (7%) | catalogued as COSV59704995; called by muse, mutect2
- CEMIP | c.111T>G p.P37= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV54989789; called by muse, mutect2
- CLRN3 | c.471C>T p.S157= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs761057423, COSV64098331; called by muse, mutect2, varscan2
- CLUL1 | c.1155G>A p.V385= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV58111606; called by muse, mutect2, varscan2
- CMSS1 | c.540A>G p.G180= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV70436050; called by muse, mutect2, varscan2
- DAPP1 | c.366G>A p.L122= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs769979490, COSV56453851; called by mutect2, varscan2
- DDIAS | c.2949T>G p.P983= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV61271712; called by muse, mutect2, varscan2
- EFR3A | c.255C>T p.L85= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV54454731; called by muse, mutect2
- FAM104B | c.312C>G p.L104= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV59775993; called by muse, mutect2, varscan2
- FAT4 | c.10557C>G p.V3519= | Silent (SNP) | VAF 8/200 reads (4%) | catalogued as COSV100627631, COSV58676462; called by muse, mutect2
- FSCN3 | c.1347C>A p.G449= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56169367; called by muse, mutect2, varscan2
- GNB2 | c.519A>T p.T173= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99309928; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.321G>A p.L107= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV59823017; called by muse, mutect2, varscan2
- KCNB1 | c.1875C>A p.G625= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV65566911, COSV65570834; called by muse, mutect2
- MLLT10 | c.1905C>T p.L635= (on ENST00000307729 / NM_001195626.3; = p.L651= on NM_004641.3) | Silent (SNP) | VAF 30/305 reads (10%) | catalogued as COSV56993128; called by muse, mutect2
- MYH4 | c.3912G>A p.Q1304= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV55114495; called by muse, mutect2, varscan2
- NELL2 | c.366G>T p.R122= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV61571518; called by muse, mutect2, varscan2
- NPY2R | c.138G>A p.L46= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV61527610; called by muse, mutect2, varscan2
- OVCH2 | c.741G>T p.R247= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV71952747; called by muse, mutect2, varscan2
- PCDHB2 | c.2037A>C p.A679= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs782157194, COSV50599885; called by muse, mutect2
- PCDHGB2 | c.696C>T p.V232= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1179144705, COSV53917499; called by mutect2, varscan2
- PCGF1 | c.219G>A p.V73= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs1244421102, COSV52042444; called by muse, mutect2, varscan2
- PKD1L1 | c.6426G>A p.G2142= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV56961032; called by muse, mutect2, varscan2
- POFUT1 | c.453C>T p.F151= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV65260073, COSV65260467; called by muse, mutect2
- PPP1R16A | c.421C>T p.L141= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV52952605; called by muse, mutect2
- PRC1 | c.1668G>C p.L556= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV62694701; called by muse, mutect2
- RB1CC1 | c.3255G>A p.Q1085= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV50244435, COSV50270164; called by muse, mutect2, varscan2
- RGS22 | c.3237T>C p.I1079= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV62659245; called by muse, mutect2, varscan2
- ROS1 | c.5433C>T p.C1811= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs775276256, COSV63853110; called by muse, mutect2, varscan2
- RYR2 | c.1335C>A p.V445= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV63670650, COSV63675421; called by muse, mutect2, varscan2
- SETBP1 | c.303A>T p.G101= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV56316296; called by muse, mutect2, varscan2
- SLC18A3 | c.1149A>T p.L383= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60322052; called by muse, mutect2, varscan2
- SPTBN4 | c.7425C>G p.L2475= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs200712024, COSV52538580; called by muse, mutect2
- SV2B | c.63C>T p.R21= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs191343592; called by muse, varscan2
- TENM2 | c.5940C>T p.I1980= (on ENST00000518659 / NM_001122679.2; = p.I1741= on NM_001080428.3) | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs771284024, COSV69124898; called by muse, mutect2, varscan2
- TNFSF4 | c.387G>A p.L129= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV56056185; called by muse, mutect2, varscan2
- TSHZ3 | c.669C>T p.Y223= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as rs780383188, COSV53667135; called by muse, mutect2, varscan2
- TTN | c.49755G>A p.L16585= (on ENST00000591111; = p.L9161= on NM_003319.4) | Silent (SNP) | VAF 30/444 reads (7%) | catalogued as COSV59949395; called by muse, mutect2
- TXNRD2 | c.1359G>C p.L453= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV68691818; called by muse, mutect2
- WDFY3 | c.4989G>A p.V1663= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV55696306; called by muse, mutect2
- ZNF286A | c.753C>G p.L251= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV67845259; called by muse, mutect2, varscan2
- PCDH15 | c.91+56224G>C | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as COSV57278174; called by muse, mutect2, varscan2
